MMRF case MMRF_2197 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b578282f-0222-4e0b-af52-39c68484ae4d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.0 years (29,953 days); Days to last known disease status: 82 days; Days to last follow up: 82 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5: M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 347 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13 mg/dL; Immunoglobulin G 30.4 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.92 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 130 µmol/L; Calcium 2.95 mmol/L; Albumin 37.4 g/L; Glucose 5.23 mmol/L; C-Reactive Protein 0.342 mg/dL.
- Day 82: Hemoglobin 6.2 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 237 ×10⁹/L.

Other clinical attributes
- Day -5: Weight: 70 kg; Height: 173 cm.

Biospecimens (2 samples)
- Sample MMRF_2197_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2197_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
